CCDI case PBCCUM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9351b47f-9778-4b7a-a5a5-adf23e01ecd1

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 2.1 years (765 days).

Biospecimens (2 samples)
- Sample 0DP7LJ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPYE8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
